Somatic mutation profile of tumor specimen TARGET-10-PATZVD-09A (aliquot TARGET-10-PATZVD-09A-01D) from TARGET case TARGET-10-PATZVD, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.2 years (1,518 days).
Specimen TARGET-10-PATZVD-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3cba4368-0fb7-49f9-a968-734be2f40289.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATZVD-10A (Blood Derived Normal), aliquot TARGET-10-PATZVD-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/034ae345-d86f-456c-b05e-3df8e8c617e5

The open-access MAF lists 21 somatic variants for this specimen: 12 protein-altering or splice-affecting, 5 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 5, RNA 2, 5'UTR 1, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PHF6 | c.820C>T p.R274* (on ENST00000332070 / NM_032458.3; = p.R275* on NM_032335.3) | Nonsense Mutation (SNP) | VAF 52/61 reads (85%) | catalogued as rs1556019107, COSV59699330; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ANK3 | c.10838G>A p.R3613H | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV55050330, COSV55057604; called by mutect2, varscan2
- AOX1 | c.2756C>T p.A919V | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as rs1470559474; called by mutect2, varscan2
- CD180 | c.319G>T p.V107L | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.138); catalogued as rs1427871669; called by muse, mutect2
- CPB2 | c.907A>G p.I303V | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.076); catalogued as COSV51677597; called by muse, mutect2, varscan2
- EPHB2 | c.199T>C p.S67P | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV65867096; called by muse, mutect2, varscan2
- ITGB4 | c.179G>A p.R60H | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746305033, COSV52333297; called by muse, mutect2, varscan2
- NOTCH1 | c.4847T>A p.I1616N | Missense Mutation (SNP) | VAF 52/131 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53028112; called by muse, mutect2, varscan2
- PCDH11X | c.3509C>T p.A1170V | Missense Mutation (SNP) | VAF 75/94 reads (80%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.017); catalogued as rs767095460, COSV53507796; called by muse, mutect2, varscan2
- CAMK1D | c.750C>A p.D250E | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0.074); called by muse, varscan2
- PRUNE2 | c.7942G>T p.A2648S | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.057); called by muse, mutect2
- SAMM50 | c.750C>A p.S250R | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); called by mutect2, varscan2
- CPAMD8 | c.3672C>T p.T1224= (on ENST00000651564; = p.T1177= on NM_015692.5) | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as rs180687201; called by muse, mutect2, varscan2
- MCF2L | c.1008C>T p.F336= (on ENST00000375608; = p.F304= on NM_024979.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as rs997855764; called by muse, mutect2, varscan2
- MOV10 | c.1536G>A p.T512= | Silent (SNP) | VAF 4/43 reads (9%) | catalogued as rs754526699, COSV62492489; called by mutect2, varscan2
- SCUBE1 | c.2898G>A p.E966= | Silent (SNP) | VAF 29/87 reads (33%) | called by muse, mutect2, varscan2
- SLC12A6 | c.2601C>T p.S867= (on ENST00000354181 / NM_001365088.1; = p.S816= on NM_005135.2) | Silent (SNP) | VAF 95/227 reads (42%) | catalogued as rs765423681; called by muse, mutect2, varscan2
- ADAM21P1 | n.1619T>C | RNA (SNP) | VAF 47/133 reads (35%) | catalogued as rs750940537; called by muse, mutect2, varscan2
- ERCC6 | c.1397+6974G>T | Intron (SNP) | VAF 4/33 reads (12%) | catalogued as rs754361376, COSV100876154; called by mutect2, varscan2
- LY6K | c.-11C>T | 5'UTR (SNP) | VAF 15/29 reads (52%) | catalogued as rs782589988; called by muse, mutect2, varscan2
- MST1L | n.1031G>A | RNA (SNP) | VAF 18/68 reads (26%) | catalogued as rs574029984; called by muse, varscan2
